Somatic mutation profile of tumor specimen MP2PRT-PAUPBA-TMP1-A (aliquot MP2PRT-PAUPBA-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUPBA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,527 days).
Specimen MP2PRT-PAUPBA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 502f1813-cf7d-4314-b7f4-a32d9714b0d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPBA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPBA-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21cb964-3227-4c3a-9236-8517873bcfc1

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN2A1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs777833408; called by muse, mutect2, varscan2
- EPHA3 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV100347680; called by muse, varscan2
- GGT2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1225341378; called by muse, mutect2, varscan2
- PIP5K1B | c.1477G>C p.D493H | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV55255994; called by muse, mutect2, varscan2
- SERINC5 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs1258715796, COSV72596230; called by muse, mutect2
- SLC1A7 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775909830, COSV65194890; called by muse, mutect2, varscan2
- TPPP | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs377528137; called by muse, mutect2, varscan2
- BRWD3 | c.3283G>C p.E1095Q | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC2 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 81/523 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IGHV1-69 | c.349_350insTTCGAGG p.R117Ifs*? | Frame Shift Ins (INS) | VAF 34/42 reads (81%) | called by pindel, varscan2
- NAP1L5 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 218/487 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSD | c.1910T>A p.F637Y | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAHD1 | c.99G>A p.E33= | Silent (SNP) | VAF 97/546 reads (18%) | catalogued as COSV66899650; called by muse, mutect2, varscan2
- OR56A4 | c.1062C>T p.I354= | Silent (SNP) | VAF 15/446 reads (3%) | called by muse, mutect2
- RP2 | c.45G>A p.S15= | Silent (SNP) | VAF 181/416 reads (44%) | called by muse, mutect2, varscan2
